Somatic mutation profile of tumor specimen TCGA-66-2791-01A (aliquot TCGA-66-2791-01A-01D-0983-08) from TCGA case TCGA-66-2791, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 66.1 years (24,138 days).
Specimen TCGA-66-2791-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07faf0df-7da2-450d-8e21-f0a770a559e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-66-2791-11A (Solid Tissue Normal), aliquot TCGA-66-2791-11A-01D-0983-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4108be9d-27bc-4a90-b608-af76b36546b6

The open-access MAF lists 327 somatic variants for this specimen: 239 protein-altering or splice-affecting, 80 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 200, Silent 80, Nonsense Mutation 20, Frame Shift Del 11, Frame Shift Ins 3, Intron 3, Splice Site 3, RNA 3, Splice Region 2, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KDM6A | c.2832+1G>A p.X944_splice | Splice Site (SNP) | VAF 28/59 reads (47%) | catalogued as rs1135401809, COSV65037460, COSV65040731; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 10/40 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACOX3 | c.1641G>C p.R547S | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV62711976; called by muse, varscan2
- ACSM1 | c.994A>G p.I332V | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV54635607; called by muse, mutect2, varscan2
- ADAM29 | c.997C>A p.H333N | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.681); catalogued as COSV63663498, COSV63664733; called by muse, mutect2, varscan2
- ADAM29 | c.1589G>C p.R530P | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63663505; called by muse, mutect2, varscan2
- ADGRF4 | c.1157C>A p.S386Y | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51952288; called by muse, mutect2, varscan2
- ADGRG3 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.76); PolyPhen benign (0.011); catalogued as rs757693632, COSV59651088; called by muse, mutect2, varscan2
- AKAP6 | c.4267C>T p.P1423S | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.001); catalogued as rs1356474184, COSV55213508; called by muse, mutect2, varscan2
- AP2B1 | c.802G>C p.E268Q | Missense Mutation (SNP) | VAF 49/196 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.139); catalogued as COSV51999371; called by muse, mutect2, varscan2
- ARHGAP31 | c.2076_2077insA p.F693Ifs*28 | Frame Shift Ins (INS) | VAF 33/141 reads (23%) | catalogued as COSV99957137; called by mutect2, pindel, varscan2
- ARHGAP36 | c.158A>G p.H53R | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); catalogued as rs1364616603, COSV52266567; called by muse, mutect2, varscan2
- ARID5B | c.3073G>A p.G1025R | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.307); catalogued as COSV54420185; called by muse, mutect2, varscan2
- ASB2 | c.228G>T p.M76I | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.525); catalogued as COSV60111842; called by muse, mutect2, varscan2
- ASCL4 | c.40C>A p.P14T | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV60816606; called by muse, mutect2, varscan2
- ATP5MC3 | c.290G>T p.G97V | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52976420; called by muse, mutect2, varscan2
- ATP8A1 | c.364-1G>A p.X122_splice | Splice Site (SNP) | VAF 7/38 reads (18%) | catalogued as COSV52534889; called by muse, mutect2, varscan2
- ATXN2L | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs776614927, COSV57366960; called by muse, mutect2, varscan2
- BICRAL | c.1751C>A p.S584Y | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV58405360; called by muse, mutect2, varscan2
- BMP5 | c.290C>A p.S97* | Nonsense Mutation (SNP) | VAF 34/111 reads (31%) | catalogued as COSV63703116; called by muse, mutect2, varscan2
- BRINP2 | c.2285C>A p.S762Y | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as COSV64176582, COSV64177443; called by muse, mutect2, varscan2
- C16orf86 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.214); catalogued as COSV54751723; called by muse, mutect2, varscan2
- C6orf136 | c.667G>A p.E223K (on ENST00000376473 / NM_001109938.3; = p.E89K on NM_145029.4) | Missense Mutation (SNP) | VAF 66/256 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.591); catalogued as COSV53313933; called by muse, mutect2, varscan2
- CCR6 | c.199G>T p.V67L | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59475036, COSV59476143; called by muse, mutect2, varscan2
- CD200 | c.559G>T p.A187S (on ENST00000473539 / NM_001004196.3; = p.A162S on NM_005944.7 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV59863218; called by muse, mutect2, varscan2
- CD99 | c.274G>C p.D92H | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV66989346, COSV66989402; called by muse, varscan2
- CDH10 | c.1913G>T p.R638L | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV52570966, COSV52580434; called by muse, mutect2, varscan2
- CDH8 | c.1265C>A p.S422Y | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV54866428, COSV54887800; called by muse, mutect2, varscan2
- CDHR1 | c.1843G>A p.E615K | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.761); catalogued as rs144856473, COSV60561516; called by muse, mutect2, varscan2
- CDK18 | c.688G>T p.A230S (on ENST00000506784 / NM_212503.3; = p.A200S on NM_002596.4) | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.692); catalogued as COSV63727446; called by mutect2, varscan2
- CDK19 | c.532A>T p.R178* | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | catalogued as COSV60449260; called by muse, mutect2
- CERKL | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV59207344; called by muse, mutect2, varscan2
- CHRM2 | c.726G>T p.K242N | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.314); catalogued as COSV57771981; called by muse, mutect2, varscan2
- CHST5 | c.474C>A p.S158R | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.805); catalogued as COSV60339042; called by muse, mutect2, varscan2
- CLDN10 | c.58G>A p.V20I | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV65297453; called by muse, mutect2, varscan2
- CLRN2 | c.645G>C p.E215D | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.01); catalogued as COSV71825205, COSV71825226; called by muse, mutect2, varscan2
- CNOT3 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1462458263, COSV55363110; called by muse, mutect2, varscan2
- CNPPD1 | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs551627689, COSV55407182; called by muse, mutect2, varscan2
- COL19A1 | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 53/186 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV59572618; called by muse, mutect2, varscan2
- CORO1C | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.044); catalogued as rs771989893, COSV54595807; called by muse, mutect2, varscan2
- CPA4 | c.844G>C p.A282P | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.12); catalogued as COSV55983252, COSV55983743; called by muse, mutect2, varscan2
- CR2 | c.2569A>G p.T857A | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as COSV65507575; called by muse, mutect2, varscan2
- CRB1 | c.3376C>A p.L1126I | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.994); catalogued as rs149390998, COSV66328659; called by muse, mutect2, varscan2
- CUBN | c.9619del p.E3207Rfs*14 | Frame Shift Del (DEL) | VAF 12/60 reads (20%) | catalogued as COSV100912354, COSV64715276; called by mutect2, pindel, varscan2
- DOCK9 | c.5793G>C p.K1931N (on ENST00000376460 / NM_001366676.2; = p.K1932N on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59628772; called by muse, mutect2, varscan2
- DOP1A | c.2421G>C p.Q807H | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs749894496, COSV52710184; called by muse, mutect2, varscan2
- DOP1B | c.2830G>C p.E944Q | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.619); catalogued as COSV67693346; called by muse, mutect2, varscan2
- DPF3 | c.165C>G p.I55M | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV63500175; called by muse, mutect2, varscan2
- DROSHA | c.3151G>A p.V1051I | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.055); catalogued as COSV60775912; called by muse, mutect2, varscan2
- DYNC1I1 | c.793G>T p.G265W | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV61457929; called by muse, mutect2, varscan2
- EFCAB6 | c.3295A>C p.K1099Q | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as COSV53063038; called by muse, mutect2, varscan2
- ELN | c.1672G>A p.G558S | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.55); catalogued as rs782373144, COSV52710107; called by muse, mutect2, varscan2
- ERO1A | c.820G>C p.E274Q | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.026); catalogued as COSV67471169; called by muse, mutect2, varscan2
- ETFDH | c.976G>A p.G326S | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.354); catalogued as CM1313484, COSV57014909; called by muse, mutect2, varscan2
- FAM171B | c.773T>A p.I258K | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as COSV59003413; called by muse, mutect2, varscan2
- FAT1 | c.7349C>G p.S2450* | Nonsense Mutation (SNP) | VAF 36/158 reads (23%) | catalogued as COSV71673814, COSV71675311; called by muse, mutect2, varscan2
- FSCB | c.2327T>A p.V776D | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT tolerated (0.68); PolyPhen benign (0.026); catalogued as COSV61217940; called by muse, mutect2, varscan2
- FTSJ3 | c.574G>C p.E192Q | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59562496; called by muse, mutect2, varscan2
- FUT9 | c.177T>G p.D59E | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as COSV56146681; called by muse, mutect2, varscan2
- GCC2 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 49/143 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV59176299; called by muse, mutect2, varscan2
- GIGYF2 | c.2815C>G p.Q939E | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.281); catalogued as COSV65249300, COSV65251274; called by muse, mutect2, varscan2
- GPX6 | c.521T>C p.M174T | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV62657488; called by muse, mutect2, varscan2
- GREB1 | c.4358C>T p.A1453V | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as COSV52186839; called by muse, mutect2, varscan2
- HAL | c.575G>T p.R192L | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.797); catalogued as COSV54116399, COSV54117788; called by muse, mutect2, varscan2
- HCN1 | c.2308A>G p.S770G | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV57509919; called by muse, mutect2, varscan2
- HDAC9 | c.439C>A p.L147I | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67772941; called by muse, mutect2, varscan2
- HIF3A | c.408T>A p.C136* (on ENST00000377670 / NM_152795.4; = p.C67* on NM_022462.4) | Nonsense Mutation (SNP) | VAF 29/119 reads (24%) | catalogued as COSV52198283; called by muse, mutect2, varscan2
- HOOK2 | c.1580A>T p.Q527L | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767288771, COSV53402299; called by muse, mutect2, varscan2
- IGFL3 | c.317G>A p.C106Y | Missense Mutation (SNP) | VAF 78/296 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58242745; called by muse, mutect2, varscan2
- IGKV3-15 | c.236C>A p.P79Q | Missense Mutation (SNP) | VAF 48/181 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs530316441; called by muse, mutect2, varscan2
- IGKV3-15 | c.235C>G p.P79A | Missense Mutation (SNP) | VAF 45/176 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as rs774692356; called by muse, mutect2, varscan2
- IL10 | c.376T>C p.C126R | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65594527; called by muse, mutect2
- IL13RA1 | c.806C>G p.T269S | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65426364; called by muse, mutect2, varscan2
- KCNA5 | c.418C>G p.Q140E | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV52905635; called by muse, mutect2, varscan2
- KCTD16 | c.736C>A p.H246N | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV72578696; called by muse, mutect2, varscan2
- KDM5C | c.1840G>T p.A614S | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.286); catalogued as COSV64764875; called by muse, mutect2, varscan2
- KDR | c.452T>G p.L151R | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV55764893; called by muse, mutect2, varscan2
- KHSRP | c.327G>T p.K109N | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV58599760; called by muse, mutect2, varscan2
- KIF13B | c.2830G>A p.E944K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as rs764266402, COSV72954389; called by muse, mutect2, varscan2
- LAMA2 | c.7085C>G p.S2362C | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV70346853; called by muse, mutect2, varscan2
- LAMA4 | c.1298G>T p.R433L (on ENST00000230538 / NM_001105206.3; = p.R426L on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV57896588, COSV57898555; called by muse, mutect2, varscan2
- LARP7 | c.926G>T p.R309L | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV60520917; called by muse, mutect2, varscan2
- LIG4 | c.2059G>T p.G687C | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63597029; called by muse, mutect2, varscan2
- LRFN5 | c.756G>C p.R252S | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53255679; called by muse, mutect2, varscan2
- LRRTM1 | c.916C>A p.L306M | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99702267; called by mutect2, varscan2
- MAGEC1 | c.3038A>G p.Y1013C | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201330612, COSV53572600; called by muse, mutect2, varscan2
- MAGEC3 | c.1929G>T p.E643D | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.341); catalogued as COSV53580113; called by muse, mutect2, varscan2
- MARK4 | c.809G>C p.R270T | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53463196, COSV53463823; called by muse, mutect2, varscan2
- MED17 | c.1834G>T p.D612Y | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV52600909; called by muse, varscan2
- MED28 | c.136G>C p.D46H | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52846234; called by muse, mutect2, varscan2
- MIA3 | c.4809C>A p.L1603= | Splice Region (SNP) | VAF 22/60 reads (37%) | catalogued as COSV60512722; called by muse, mutect2, varscan2
- MLIP | c.1117G>T p.V373L | Missense Mutation (SNP) | VAF 61/270 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.043); catalogued as COSV51429726, COSV51430920; called by muse, mutect2, varscan2
- MLLT10 | c.923C>G p.S308* | Nonsense Mutation (SNP) | VAF 15/49 reads (31%) | catalogued as COSV56995741; called by muse, mutect2, varscan2
- MN1 | c.1487G>A p.G496D | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56558279; called by muse, mutect2
- MST1R | c.3691C>T p.R1231C | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777514800, COSV56568655, COSV99618641; called by muse, mutect2, varscan2
- MYH2 | c.5270C>T p.A1757V | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.107); catalogued as COSV55438029; called by muse, mutect2, varscan2
- N4BP2L2 | c.1001A>G p.N334S | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV57228355; called by muse, mutect2, varscan2
- NALCN | c.3103G>A p.G1035R | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51934806; called by muse, mutect2, varscan2
- NAV3 | c.4333C>T p.R1445C | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760922961, COSV57078990, COSV57117271; called by muse, mutect2, varscan2
- NCAM1 | c.1171G>T p.G391* (on ENST00000316851 / NM_181351.5; = p.G381* on NM_000615.7) | Nonsense Mutation (SNP) | VAF 15/82 reads (18%) | catalogued as COSV100376872, COSV100377786; called by muse, mutect2, varscan2
- NCSTN | c.1394T>G p.V465G | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV54187567; called by muse, mutect2, varscan2
- NEPRO | c.1441A>G p.T481A | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV55606491; called by muse, mutect2, varscan2
- NFRKB | c.130G>T p.E44* (on ENST00000446488 / NM_001143835.2; = p.E57* on NM_006165.3) | Nonsense Mutation (SNP) | VAF 16/92 reads (17%) | catalogued as COSV58756423, COSV58757920; called by muse, mutect2, varscan2
- NGDN | c.529G>T p.V177F | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV68142388; called by muse, mutect2, varscan2
- NLRP4 | c.2642T>C p.V881A | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.529); catalogued as COSV56713333; called by muse, mutect2, varscan2
- NLRP5 | c.1553del p.R518Pfs*11 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | catalogued as COSV66763107; called by mutect2, pindel, varscan2
- NPAP1 | c.3170C>G p.A1057G | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV61506879; called by muse, mutect2, varscan2
- NPHS2 | c.572C>A p.A191D | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62635250, COSV62635361, COSV62636871; called by muse, mutect2, varscan2
- NUCB2 | c.650A>C p.H217P | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60375143; called by muse, varscan2
- NUP133 | c.3349G>A p.E1117K | Missense Mutation (SNP) | VAF 12/139 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.341); catalogued as COSV54570924; called by muse, mutect2, varscan2
- NYAP2 | c.1886C>T p.P629L | Missense Mutation (SNP) | VAF 80/210 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV56004663; called by muse, mutect2, varscan2
- OAT | c.607G>T p.G203* | Nonsense Mutation (SNP) | VAF 14/49 reads (29%) | catalogued as COSV64347673; called by muse, mutect2, varscan2
- OR10W1 | c.452T>G p.V151G | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV67720429; called by muse, varscan2
- OR2G3 | c.271A>G p.T91A | Missense Mutation (SNP) | VAF 63/201 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV60681652; called by muse, mutect2, varscan2
- OR2L8 | c.898C>A p.L300M | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.505); catalogued as COSV61726752; called by muse, varscan2
- OR4A15 | c.348G>T p.M116I | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.275); catalogued as COSV59035234; called by muse, varscan2
- OR4M1 | c.477G>C p.Q159H | Missense Mutation (SNP) | VAF 26/380 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.113); catalogued as COSV60061283; called by muse, mutect2
- OR4Q3 | c.470G>C p.C157S | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.121); catalogued as COSV59178657; called by muse, mutect2, varscan2
- OR4S2 | c.60G>T p.E20D | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV56746785, COSV56746840; called by muse, mutect2, varscan2
- OR5D13 | c.321C>A p.C107* | Nonsense Mutation (SNP) | VAF 26/125 reads (21%) | catalogued as rs760709569, COSV62333668; called by muse, mutect2, varscan2
- OR5L1 | c.301T>C p.F101L | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as COSV61733811; called by muse, mutect2, varscan2
- OR5V1 | c.246G>A p.M82I | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as COSV65827871; called by muse, mutect2, varscan2
- OTOGL | c.1636G>C p.D546H (on ENST00000547103; = p.D537H on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101509276; called by muse, mutect2
- P2RY2 | c.316T>A p.C106S | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60776186; called by muse, mutect2, varscan2
- PAN2 | c.2956G>A p.E986K (on ENST00000425394 / NM_001127460.3; = p.E982K on NM_014871.5) | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as rs1282480792, COSV56264347; called by muse, mutect2, varscan2
- PCDHA2 | c.713A>G p.N238S | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.524); catalogued as COSV65366930; called by muse, mutect2, varscan2
- PCDHB4 | c.1331A>G p.N444S | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1323480818, COSV52022290; called by muse, mutect2, varscan2
- PCDHB8 | c.995G>A p.C332Y | Missense Mutation (SNP) | VAF 40/290 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV50767218; called by muse, mutect2, varscan2
- PCDHGB2 | c.1622C>T p.A541V | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.916); catalogued as rs1160428745, COSV53945560; called by muse, mutect2, varscan2
- PCNX2 | c.4393G>T p.G1465C | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV50799899; called by muse, mutect2, varscan2
- PDSS2 | c.1051A>T p.R351* | Nonsense Mutation (SNP) | VAF 8/47 reads (17%) | catalogued as COSV64654901; called by muse, mutect2, varscan2
- PIEZO2 | c.6847G>A p.E2283K | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV53287755; called by muse, mutect2, varscan2
- PKP4 | c.3323G>A p.R1108Q | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.775); catalogued as COSV61578691; called by muse, mutect2, varscan2
- PLEKHS1 | c.907C>A p.Q303K (on ENST00000369310 / NM_182601.1; = p.Q309K on NM_024889.5) | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.12); catalogued as COSV63054718; called by muse, mutect2, varscan2
- PMFBP1 | c.1342G>C p.A448P | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.571); catalogued as COSV52823954; called by muse, mutect2, varscan2
- PPIP5K1 | c.3966G>T p.E1322D (on ENST00000396923; = p.E1297D on NM_014659.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.022); catalogued as COSV55808602; called by muse, mutect2, varscan2
- PPRC1 | c.3287C>T p.A1096V | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs1221047579, COSV53385304; called by muse, mutect2, varscan2
- PRAG1 | c.2162G>A p.R721Q | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.807); catalogued as rs375344955, COSV58163858; called by muse, mutect2, varscan2
- PRKCD | c.100G>C p.E34Q | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV57848491; called by muse, mutect2, varscan2
- PSG1 | c.255C>A p.D85E | Missense Mutation (SNP) | VAF 55/261 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.624); catalogued as rs1058959, COSV54944619, COSV54949080; called by muse, mutect2, varscan2
- PSG6 | c.550C>G p.Q184E | Missense Mutation (SNP) | VAF 54/226 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.314); catalogued as rs1238898452, COSV51832912; called by muse, mutect2, varscan2
- PSMC5 | c.811C>G p.R271G | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56739251; called by muse, mutect2, varscan2
- PTCD1 | c.1486G>C p.V496L | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV52863442; called by muse, mutect2, varscan2
- QRSL1 | c.1109A>G p.N370S | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.088); catalogued as COSV64687470; called by muse, mutect2, varscan2
- QSER1 | c.3944C>G p.S1315* (on ENST00000399302; = p.S1444* on NM_001076786.3) | Nonsense Mutation (SNP) | VAF 14/49 reads (29%) | catalogued as COSV101234936, COSV67900520; called by muse, mutect2, varscan2
- RALGAPA1 | c.803A>T p.D268V | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); catalogued as COSV51882527; called by muse, mutect2, varscan2
- RANBP17 | c.2005A>G p.T669A | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.061); catalogued as COSV66649990; called by muse, mutect2, varscan2
- RBM10 | c.2125A>G p.T709A | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as COSV61309043; called by muse, mutect2, varscan2
- RBM6 | c.3322C>T p.R1108* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as COSV56482692; called by muse, mutect2, varscan2
- RGL1 | c.998C>T p.S333L (on ENST00000360851 / NM_001297672.2; = p.S368L on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1157857351, COSV58982050; called by muse, mutect2, varscan2
- RGS16 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as rs1374633959, COSV62375694; called by muse, mutect2, varscan2
- RGS21 | c.442T>C p.W148R | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.015); catalogued as rs1402350955, COSV69882341, COSV69882422; called by muse, mutect2, varscan2
- RIC1 | c.1473G>T p.E491D | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.053); catalogued as COSV52609456; called by muse, mutect2, varscan2
- RP1 | c.4627G>C p.D1543H | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV55116509; called by muse, mutect2, varscan2
- RPTOR | c.3153G>A p.W1051* | Nonsense Mutation (SNP) | VAF 7/33 reads (21%) | catalogued as COSV60808387; called by muse, mutect2, varscan2
- SACS | c.11885T>C p.I3962T | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV66539730; called by muse, mutect2, varscan2
- SCN1A | c.1531G>A p.G511S | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.092); catalogued as COSV57669646; called by muse, mutect2, varscan2
- SERPING1 | c.379G>A p.V127I | Missense Mutation (SNP) | VAF 41/180 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV53542452; called by muse, mutect2, varscan2
- SGCA | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as COSV56249268; called by muse, mutect2, varscan2
- SHC3 | c.1066C>T p.L356F | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV65438338; called by muse, mutect2, varscan2
- SIGLEC9 | c.419C>A p.T140K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.636); catalogued as COSV51584313; called by muse, mutect2, varscan2
- SKIV2L | c.3094C>T p.Q1032* | Nonsense Mutation (SNP) | VAF 8/77 reads (10%) | catalogued as COSV61713584; called by mutect2, varscan2
- SLC12A7 | c.757G>T p.V253L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.298); catalogued as COSV53757177; called by muse, mutect2
- SLC25A13 | c.544G>T p.D182Y | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55707142; called by muse, mutect2, varscan2
- SNAP91 | c.34G>T p.A12S | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52121866; called by muse, mutect2, varscan2
- SORCS1 | c.1531C>A p.L511I | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.844); catalogued as COSV53865564; called by muse, mutect2, varscan2
- SOS1 | c.124G>C p.D42H | Missense Mutation (SNP) | VAF 35/208 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV67675185; called by muse, mutect2, varscan2
- SPATA7 | c.49G>T p.G17C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV50417068; called by muse, varscan2
- SPEN | c.3955C>T p.Q1319* | Nonsense Mutation (SNP) | VAF 11/55 reads (20%) | catalogued as COSV65361640; called by muse, mutect2, varscan2
- SPHKAP | c.3731C>A p.S1244Y | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV60878332; called by muse, mutect2, varscan2
- SPNS1 | c.1224C>T p.Y408= | Splice Region (SNP) | VAF 6/23 reads (26%) | catalogued as rs201354349, COSV57954689; called by mutect2, varscan2
- SPTAN1 | c.1808A>G p.D603G | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63987082; called by muse, mutect2, varscan2
- SPTLC2 | c.1349G>A p.R450K | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53639766; called by muse, mutect2
- STIM1 | c.1371C>G p.D457E | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs777537168, COSV56154580; called by muse, mutect2, varscan2
- STIM2 | c.191A>G p.E64G | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.212); catalogued as COSV52838894; called by muse, mutect2, varscan2
- SUSD6 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV61365353; called by muse, mutect2, varscan2
- SYNE2 | c.20639A>G p.N6880S | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764411722, COSV59950700; called by muse, mutect2, varscan2
- SYT5 | c.540+1G>A p.X180_splice | Splice Site (SNP) | VAF 22/77 reads (29%) | catalogued as rs750121068, COSV62830304, COSV62830720; called by muse, mutect2, varscan2
- SYTL2 | c.1513A>T p.R505W | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100314280, COSV60364522; called by muse, mutect2, varscan2
- TAB3 | c.932T>C p.V311A | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.86); PolyPhen benign (0.202); catalogued as COSV55836851; called by muse, mutect2, varscan2
- TAS2R20 | c.268G>A p.V90I | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.173); catalogued as COSV67855696; called by muse, mutect2, varscan2
- TAS2R8 | c.924G>A p.M308I | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV53688825; called by muse, mutect2, varscan2
- TBX18 | c.374C>T p.S125F | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1441271498, COSV63736795; called by muse, varscan2
- TCTN2 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV57632886; called by muse, mutect2, varscan2
- TEX101 | c.470G>T p.C157F (on ENST00000598265 / NM_001130011.3; = p.C175F on NM_031451.4) | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53661876; called by muse, mutect2, varscan2
- TEX15 | c.4144G>C p.E1382Q (on ENST00000256246; = p.E1765Q on NM_001350162.2) | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV56346285; called by muse, mutect2, varscan2
- TGFBR2 | c.884C>G p.S295* | Nonsense Mutation (SNP) | VAF 25/69 reads (36%) | catalogued as COSV55448334; called by muse, mutect2, varscan2
- TMEM248 | c.274G>A p.G92R | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.84); PolyPhen benign (0.313); catalogued as rs56128303, COSV100447377, COSV58577390; called by mutect2, varscan2
- TMPRSS15 | c.2347C>T p.P783S | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.012); catalogued as COSV53039596, COSV53048546; called by muse, mutect2, varscan2
- TNXB | c.6136C>T p.P2046S (on ENST00000647633; = p.P1799S on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.435); catalogued as COSV64478778; called by muse, mutect2, varscan2
- TOM1 | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65897996; called by muse, mutect2, varscan2
- TOPBP1 | c.3490C>G p.P1164A | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.96); catalogued as COSV53435759; called by muse, mutect2, varscan2
- TRIM39 | c.1489C>T p.P497S | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.982); catalogued as COSV64955337; called by muse, mutect2, varscan2
- TRIO | c.1279G>C p.E427Q | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.708); catalogued as rs747731735, COSV60083509; called by muse, mutect2, varscan2
- TTN | c.16148T>C p.V5383A (on ENST00000591111; = p.V4456A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/153 reads (14%) | PolyPhen benign (0.014); catalogued as rs1400648982, COSV60050631; called by muse, mutect2, varscan2
- TTYH1 | c.166G>T p.G56C | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56611738; called by muse, mutect2, varscan2
- TUBA3E | c.739G>A p.A247T | Missense Mutation (SNP) | VAF 42/178 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.273); catalogued as COSV56058919; called by muse, varscan2
- UBN2 | c.3854C>T p.T1285I | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.12); catalogued as COSV56030291; called by muse, mutect2, varscan2
- UBTF | c.988C>T p.Q330* | Nonsense Mutation (SNP) | VAF 26/100 reads (26%) | catalogued as rs1216025875, COSV57186068; called by muse, mutect2, varscan2
- UBTF | c.307A>C p.K103Q | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as COSV57186079, COSV57188564; called by muse, mutect2, varscan2
- USP29 | c.2712G>T p.Q904H | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.288); catalogued as COSV54142498; called by muse, varscan2
- USP34 | c.10449G>C p.L3483F | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV63724995; called by muse, mutect2, varscan2
- UTRN | c.1969C>T p.R657C | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.326); catalogued as rs770003496, COSV62335160; called by muse, mutect2, varscan2
- WIPI1 | c.979C>T p.P327S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.41); catalogued as COSV50930035; called by muse, mutect2, varscan2
- WNT8A | c.202A>T p.N68Y | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.225); catalogued as COSV64231139; called by muse, mutect2, varscan2
- XYLB | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.67); catalogued as rs939020492, COSV52913005; called by muse, mutect2, varscan2
- XYLT1 | c.2481C>A p.H827Q | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.104); catalogued as rs758501855, COSV54484171; called by mutect2, varscan2
- YTHDF3 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV72773476; called by muse, mutect2, varscan2
- ZFHX4 | c.10552C>T p.L3518F | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.93); catalogued as COSV50781668; called by muse, mutect2, varscan2
- ZIM3 | c.1211C>G p.S404* | Nonsense Mutation (SNP) | VAF 13/157 reads (8%) | catalogued as COSV54142512; called by muse, mutect2
- ZNF135 | c.967G>A p.E323K (on ENST00000313434 / NM_001289401.2; = p.E335K on NM_003436.4) | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.888); catalogued as rs762866748, COSV57879867, COSV57882102; called by muse, mutect2, varscan2
- ZNF14 | c.366G>C p.M122I | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV59849501; called by muse, mutect2, varscan2
- ZNF19 | c.325G>C p.E109Q | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as COSV55507590; called by muse, mutect2, varscan2
- ZNF208 | c.465T>A p.H155Q | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.683); catalogued as COSV68105351; called by muse, mutect2, varscan2
- ZNF28 | c.1360C>T p.L454F | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV60423131; called by muse, mutect2, varscan2
- ZNF367 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as rs757642912, COSV64546968; called by muse, mutect2, varscan2
- ZNF451 | c.2011C>A p.L671I | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.462); catalogued as COSV62597663; called by muse, varscan2
- ZNF451 | c.2093C>G p.S698* | Nonsense Mutation (SNP) | VAF 5/38 reads (13%) | catalogued as COSV62597671; called by muse, varscan2
- ZNF548 | c.1436G>A p.C479Y | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60240945; called by muse, mutect2, varscan2
- ZNF680 | c.172A>G p.K58E | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.162); catalogued as COSV59015352; called by muse, mutect2, varscan2
- ZNF681 | c.1237A>G p.K413E | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.801); catalogued as COSV68074264; called by muse, mutect2, varscan2
- ZNF790 | c.1215G>C p.W405C | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.503); catalogued as COSV63212455; called by muse, mutect2, varscan2
- ZNF80 | c.496T>C p.C166R | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.64); catalogued as rs555903765, COSV57360728; called by muse, mutect2, varscan2
- ZSCAN4 | c.1175G>T p.G392V | Missense Mutation (SNP) | VAF 45/166 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56592699, COSV56593272; called by muse, mutect2, varscan2
- ADAMTSL2 | c.1334C>A p.T445N | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AOAH | c.593del p.G198Afs*85 | Frame Shift Del (DEL) | VAF 11/102 reads (11%) | called by mutect2, pindel, varscan2
- CD19 | c.611del p.P204Lfs*23 | Frame Shift Del (DEL) | VAF 13/37 reads (35%) | called by mutect2, pindel, varscan2
- COL22A1 | c.4629del p.G1545Vfs*79 | Frame Shift Del (DEL) | VAF 10/17 reads (59%) | called by mutect2, varscan2
- CSMD2 | c.577del p.L193Cfs*119 | Frame Shift Del (DEL) | VAF 6/27 reads (22%) | called by mutect2, pindel, varscan2
- FDXACB1 | c.1554dup p.V519Cfs*9 | Frame Shift Ins (INS) | VAF 14/73 reads (19%) | called by mutect2, pindel, varscan2
- GYS2 | c.1575del p.S526Vfs*2 | Frame Shift Del (DEL) | VAF 10/57 reads (18%) | called by mutect2, pindel, varscan2
- KIR3DL2 | c.78G>T p.Q26H | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAP2K3 | c.232G>T p.V78L (on ENST00000342679 / NM_145109.3; = p.V49L on NM_002756.4) | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- MMGT1 | c.108del p.E37Kfs*7 | Frame Shift Del (DEL) | VAF 36/78 reads (46%) | called by mutect2, pindel, varscan2
- PHIP | c.2231del p.G744Efs*5 | Frame Shift Del (DEL) | VAF 9/68 reads (13%) | called by mutect2, pindel, varscan2
- PLCG2 | c.2456dup p.S821Ifs*21 | Frame Shift Ins (INS) | VAF 64/249 reads (26%) | called by mutect2, pindel, varscan2
- TTLL5 | c.2032_2038del p.I678Sfs*12 | Frame Shift Del (DEL) | VAF 10/94 reads (11%) | called by mutect2, pindel, varscan2
- VEGFC | c.1167del p.N390Tfs*29 | Frame Shift Del (DEL) | VAF 9/46 reads (20%) | called by mutect2, pindel, varscan2
- VN1R5 | c.723T>A p.Y241* | Nonsense Mutation (SNP) | VAF 35/111 reads (32%) | called by muse, mutect2, varscan2
- AADACL2 | c.129T>C p.C43= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs1372510081, COSV62930386; called by muse, mutect2, varscan2
- ABCA8 | c.3372C>A p.I1124= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as COSV52200992; called by muse, varscan2
- ADAMTS13 | c.3060C>A p.S1020= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as rs370359180, COSV63021227; called by muse, mutect2, varscan2
- ADAMTS3 | c.2946C>T p.C982= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs112565530, COSV54391169; called by muse, mutect2, varscan2
- ADGRG7 | c.774G>A p.Q258= | Silent (SNP) | VAF 25/125 reads (20%) | catalogued as COSV56296508; called by muse, varscan2
- ADGRG7 | c.801G>T p.A267= | Silent (SNP) | VAF 28/130 reads (22%) | catalogued as COSV56300493; called by muse, varscan2
- AMPH | c.1152A>G p.L384= | Silent (SNP) | VAF 15/96 reads (16%) | catalogued as COSV57741609; called by muse, mutect2, varscan2
- ANKIB1 | c.2811G>A p.L937= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as rs1461515254, COSV56061255, COSV56061767; called by muse, mutect2, varscan2
- BEND5 | c.636A>G p.V212= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as COSV65717251; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4749G>T p.S1583= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as COSV63245039; called by muse, mutect2, varscan2
- BRINP1 | c.201C>A p.T67= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV56299579; called by muse, mutect2, varscan2
- BTNL9 | c.1425C>T p.H475= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV59795801; called by mutect2, varscan2
- C16orf90 | c.388C>T p.L130= (on ENST00000399645 / NM_001353385.2; = p.L121= on NM_001080524.2) | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV68714461; called by muse, mutect2, varscan2
- C6 | c.756A>T p.T252= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as rs1340385339, COSV54709941; called by muse, mutect2, varscan2
- CYSLTR1 | c.951G>T p.V317= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV64820128; called by muse, mutect2, varscan2
- DLX1 | c.462T>G p.A154= | Silent (SNP) | VAF 37/144 reads (26%) | catalogued as COSV59394446; called by muse, mutect2, varscan2
- DNMBP | c.4701C>T p.P1567= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as rs1475257442, COSV60624979; called by muse, mutect2, varscan2
- EDNRB | c.717G>T p.L239= (on ENST00000377211 / NM_001201397.1; = p.L149= on NM_000115.5) | Silent (SNP) | VAF 34/140 reads (24%) | catalogued as COSV57522415; called by muse, mutect2, varscan2
- EFHB | c.1233A>G p.K411= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs1423404898, COSV55547965; called by mutect2, varscan2
- EHF | c.612G>C p.P204= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as COSV57668001, COSV57668160, COSV99140991; called by muse, mutect2, varscan2
- EPHA10 | c.1569C>T p.T523= | Silent (SNP) | VAF 32/94 reads (34%) | catalogued as rs1233535501, COSV57623942; called by muse, mutect2, varscan2
- FAM219B | c.451C>A p.R151= | Silent (SNP) | VAF 24/107 reads (22%) | catalogued as COSV100086299; called by muse, mutect2, varscan2
- FAT1 | c.7035C>T p.L2345= | Silent (SNP) | VAF 36/126 reads (29%) | catalogued as COSV71673817; called by muse, mutect2, varscan2
- FNIP1 | c.1626T>C p.F542= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as COSV57196247; called by muse, mutect2, varscan2
- FOXRED1 | c.1053C>A p.R351= | Silent (SNP) | VAF 20/146 reads (14%) | catalogued as COSV55006492, COSV99702828; called by muse, mutect2, varscan2
- GGT1 | c.24G>A p.L8= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV50640224; called by muse, mutect2, varscan2
- GNAS | c.552G>A p.V184= | Silent (SNP) | VAF 79/239 reads (33%) | catalogued as COSV55675931; called by muse, mutect2, varscan2
- HSPG2 | c.9600G>A p.V3200= | Silent (SNP) | VAF 41/110 reads (37%) | catalogued as COSV65933122; called by muse, mutect2, varscan2
- IGKV1D-8 | c.288C>G p.T96= | Silent (SNP) | VAF 39/231 reads (17%) | called by muse, mutect2, varscan2
- IGKV2-28 | c.309G>A p.V103= | Silent (SNP) | VAF 11/31 reads (35%) | called by mutect2, varscan2
- IGLV5-48 | c.123C>T p.C41= | Silent (SNP) | VAF 17/146 reads (12%) | catalogued as rs1226605534; called by muse, mutect2, varscan2
- IKZF2 | c.288C>G p.V96= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as COSV59578575; called by muse, mutect2, varscan2
- ITFG1 | c.1521G>A p.R507= | Silent (SNP) | VAF 21/117 reads (18%) | catalogued as COSV57748696; called by muse, mutect2, varscan2
- KDR | c.453C>A p.L151= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV55759511, COSV55776032; called by muse, mutect2, varscan2
- KIAA1210 | c.2436A>G p.Q812= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as rs780643936, COSV68177144; called by muse, mutect2, varscan2
- LRRIQ3 | c.321T>C p.N107= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV63040999; called by muse, mutect2, varscan2
- MED24 | c.1617C>T p.I539= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV62418513; called by muse, mutect2, varscan2
- MNDA | c.348C>A p.P116= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV63740784, COSV63742305; called by muse, mutect2, varscan2
- MPI | c.975C>A p.L325= | Silent (SNP) | VAF 29/108 reads (27%) | catalogued as COSV60396777; called by muse, mutect2, varscan2
- MRGPRD | c.348G>A p.L116= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV58423139; called by muse, mutect2, varscan2
- MYO15A | c.816A>G p.P272= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV52756498; called by muse, mutect2, varscan2
- NSUN6 | c.1296G>T p.P432= | Silent (SNP) | VAF 26/138 reads (19%) | catalogued as COSV99994615; called by muse, varscan2
- OR10W1 | c.819C>A p.T273= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV67720423; called by muse, mutect2, varscan2
- OR2M2 | c.810G>A p.Q270= | Silent (SNP) | VAF 34/189 reads (18%) | catalogued as COSV62898334; called by muse, mutect2, varscan2
- OR4D9 | c.402C>G p.T134= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV61434659; called by muse, mutect2, varscan2
- OR4K15 | c.936G>C p.T312= (on ENST00000305051; = p.T288= on NM_001005486.1) | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as COSV59301077, COSV59301375; called by muse, mutect2, varscan2
- PAPPA | c.3849C>G p.V1283= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV60283045; called by muse, mutect2, varscan2
- PAPPA2 | c.4458G>A p.L1486= | Silent (SNP) | VAF 34/126 reads (27%) | catalogued as COSV62792198; called by muse, mutect2, varscan2
- PARP1 | c.2817C>T p.S939= | Silent (SNP) | VAF 17/90 reads (19%) | catalogued as COSV64690310; called by muse, mutect2, varscan2
- PDZRN3 | c.2106C>T p.I702= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs570535127, COSV55199216; called by muse, mutect2, varscan2
- PER1 | c.1353G>A p.K451= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs1382603695, COSV57919401; called by muse, mutect2, varscan2
- PEX5L | c.1113G>A p.A371= | Silent (SNP) | VAF 74/162 reads (46%) | catalogued as rs757011089, COSV55839513; called by muse, mutect2, varscan2
- PNPLA4 | c.108C>T p.V36= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV66854065; called by muse, mutect2, varscan2
- PRKCB | c.1008G>A p.R336= | Silent (SNP) | VAF 25/129 reads (19%) | catalogued as rs539838175, COSV57769267; called by muse, mutect2, varscan2
- PSG4 | c.966C>T p.D322= | Silent (SNP) | VAF 39/179 reads (22%) | catalogued as rs750504490, COSV54935617; called by muse, mutect2, varscan2
- RESF1 | c.5145A>G p.L1715= | Silent (SNP) | VAF 59/227 reads (26%) | catalogued as COSV57021975; called by muse, mutect2, varscan2
- RNASEL | c.2225G>A p.*742= | Silent (SNP) | VAF 18/91 reads (20%) | catalogued as rs1200163279, COSV62376792; called by muse, mutect2, varscan2
- RRAGD | c.189G>T p.P63= | Silent (SNP) | VAF 85/353 reads (24%) | catalogued as COSV63269046; called by muse, mutect2, varscan2
- SERPINC1 | c.594T>C p.Y198= | Silent (SNP) | VAF 12/102 reads (12%) | catalogued as rs183416252, COSV62929373; ClinVar: conflicting interpretations of pathogenicity; called by mutect2, varscan2
- SLAMF8 | c.225C>T p.R75= | Silent (SNP) | VAF 33/120 reads (28%) | catalogued as COSV56988383; called by muse, mutect2, varscan2
- SLC16A5 | c.849C>T p.S283= | Silent (SNP) | VAF 104/426 reads (24%) | catalogued as COSV61675913; called by muse, mutect2, varscan2
- SMARCA2 | c.3657C>T p.A1219= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV61807224; called by muse, mutect2, varscan2
- SOX17 | c.1146T>C p.H382= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs1307624048, COSV52025630; called by muse, mutect2, varscan2
- STRC | c.3357G>A p.V1119= | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as rs1471794210, COSV70834242; called by muse, mutect2, varscan2
- TCN1 | c.882G>T p.L294= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as COSV57253194; called by muse, mutect2, varscan2
- TEAD2 | c.1008G>C p.L336= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as COSV60544320; called by muse, mutect2, varscan2
- TMEM54 | c.24G>C p.L8= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV61275468, COSV61275897; called by mutect2, varscan2
- TRIM68 | c.1194G>A p.L398= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as COSV56167974, COSV56168457, COSV56169514; called by muse, mutect2, varscan2
- TSGA10 | c.1932C>T p.A644= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as rs748720493, COSV61822580; called by muse, mutect2, varscan2
- TTC12 | c.1353C>T p.C451= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as rs1555150537, COSV59097769; called by muse, mutect2, varscan2
- UBQLN4 | c.717C>G p.L239= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as COSV64145291; called by muse, mutect2, varscan2
- URGCP | c.2454A>G p.V818= (on ENST00000453200 / NM_001077663.3; = p.V809= on NM_017920.4) | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as rs369828947; called by muse, varscan2
- USP32 | c.3957C>G p.L1319= | Silent (SNP) | VAF 37/122 reads (30%) | catalogued as COSV56268561, COSV56278749; called by muse, mutect2, varscan2
- VN1R5 | c.285C>G p.L95= | Silent (SNP) | VAF 6/126 reads (5%) | called by muse, mutect2
- WEE2 | c.246G>A p.R82= | Silent (SNP) | VAF 43/209 reads (21%) | catalogued as COSV66878869; called by muse, mutect2, varscan2
- ZDHHC20 | c.390A>G p.K130= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV57185789; called by muse, mutect2
- ZNF385B | c.159G>A p.V53= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as rs1210387532, COSV69802744; called by muse, mutect2, varscan2
- ZNF391 | c.507A>G p.E169= | Silent (SNP) | VAF 19/105 reads (18%) | catalogued as COSV55122637; called by muse, mutect2, varscan2
- ZNF462 | c.3516C>A p.P1172= | Silent (SNP) | VAF 38/169 reads (22%) | catalogued as COSV52937352, COSV99472014; called by mutect2, varscan2
- ZNF560 | c.705T>A p.T235= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as COSV56867791; called by muse, mutect2, varscan2
- FABP5P3 | chr7:152446658 del C | 3'Flank (DEL) | VAF 7/36 reads (19%) | called by mutect2, pindel*
- FAM184A | c.1815+295G>A | Intron (SNP) | VAF 15/106 reads (14%) | catalogued as COSV100137815; called by muse, mutect2, varscan2
- GLRXP3 | n.83G>T | RNA (SNP) | VAF 21/79 reads (27%) | called by muse, mutect2, varscan2
- NDUFV1 | chr11:67604831 G>T | 5'Flank (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2, varscan2
- RBFOX1 | c.28-185146C>G | Intron (SNP) | VAF 25/135 reads (19%) | catalogued as COSV100301402; called by muse, mutect2, varscan2
- RPL31P57 | n.181G>T | RNA (SNP) | VAF 5/21 reads (24%) | called by mutect2, varscan2
- SMC4 | c.687+169T>C | Intron (SNP) | VAF 6/35 reads (17%) | catalogued as COSV61004820; called by muse, mutect2, varscan2
- STAG3L4 | n.438G>T | RNA (SNP) | VAF 16/81 reads (20%) | called by muse, mutect2, varscan2
